Somatic mutation profile of tumor specimen TCGA-XF-A9SY-01A (aliquot TCGA-XF-A9SY-01A-21D-A42E-08) from TCGA case TCGA-XF-A9SY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.8 years (22,212 days).
Specimen TCGA-XF-A9SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d13896a0-5c2d-4424-a268-8df5a2f935ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SY-10A (Blood Derived Normal), aliquot TCGA-XF-A9SY-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5ae64fb-1499-4f92-9048-f070dc347614

The open-access MAF lists 440 somatic variants for this specimen: 333 protein-altering or splice-affecting, 98 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 98, Nonsense Mutation 28, Splice Site 4, Intron 3, Frame Shift Del 2, Splice Region 2, RNA 2, 5'UTR 2, 3'Flank 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs786205450, CM1312773, COSV66332601; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | hotspot (GDC flag); catalogued as rs1206165503, CM107391, COSV52661900, COSV52703354, COSV52753201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2288G>C p.W763S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229147; called by muse, mutect2
- ABCC11 | c.2897G>C p.G966A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62325212; called by muse, mutect2, varscan2
- ACTB | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV59320617; called by muse, mutect2, varscan2
- ADAM22 | c.2497A>T p.N833Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55986674; called by muse, mutect2, varscan2
- ADAMTS12 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs774886665, COSV61274356; called by muse, mutect2
- ADAMTS18 | c.1190G>T p.W397L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51399406, COSV99273440; called by muse, mutect2
- ADGRV1 | c.7412G>A p.S2471N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV67992945; called by muse, mutect2, varscan2
- ADRB2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV60005603, COSV60006058; called by muse, mutect2, varscan2
- AHNAK | c.11936G>T p.G3979V | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV57225636; called by muse, mutect2, varscan2
- AIMP2 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 9/139 reads (6%) | catalogued as COSV99774058; called by muse, mutect2
- AKNAD1 | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV62202202; called by muse, mutect2, varscan2
- AL121899.2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs927545164, COSV67352024; called by muse, mutect2, varscan2
- AMHR2 | c.1652G>A p.C551Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs199544354, COSV57686658; called by muse, mutect2, varscan2
- ANAPC16 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs138956935, COSV54965471; called by muse, mutect2, varscan2
- APAF1 | c.903G>T p.M301I (on ENST00000551964 / NM_181861.2; = p.M290I on NM_001160.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV59666949; called by muse, mutect2, varscan2
- APOH | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99235845; called by muse, mutect2
- ARFGEF3 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV99294094; called by muse, mutect2
- ARHGAP25 | c.1376A>G p.N459S (on ENST00000409202 / NM_001007231.3; = p.N451S on NM_014882.3) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV54906696; called by muse, mutect2
- ARHGAP9 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139460885, COSV57365699; called by muse, mutect2, varscan2
- ARMC2 | c.686G>T p.R229I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV64552806; called by muse, mutect2, varscan2
- ATP11B | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100017920; called by muse, mutect2, varscan2
- BAZ1A | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100701182; called by muse, mutect2
- BAZ2B | c.5498T>C p.V1833A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV58607617; called by muse, mutect2, varscan2
- BCL9L | c.2883G>A p.M961I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1419324966, COSV99419648; called by muse, mutect2
- BIN1 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV52121149; called by muse, mutect2, varscan2
- BIRC6 | c.7209G>C p.W2403C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70204108; called by muse, mutect2
- C22orf42 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV66075427; called by muse, mutect2
- C6 | c.2588G>C p.G863A | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV54716073; called by muse, mutect2
- C6orf118 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV57817922; called by muse, mutect2, varscan2
- CADM4 | c.1134C>A p.D378E | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55929635; called by muse, mutect2
- CALB1 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55368888; called by muse, mutect2, varscan2
- CAMK1D | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257797457, COSV66610289; called by muse, mutect2, varscan2
- CAPS2 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV60828046, COSV60828446; called by muse, mutect2
- CCDC8 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV56772813, COSV56774392; called by mutect2, varscan2
- CCNA1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV104371109, COSV55223403; called by muse, mutect2
- CCZ1B | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV100367923; called by muse, mutect2
- CDC27 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50647831; called by muse, mutect2, varscan2
- CDH4 | c.2145C>A p.D715E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64669808; called by muse, mutect2, varscan2
- CELA3B | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100448810; called by muse, mutect2, varscan2
- CELSR3 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV50855893, COSV51112125; called by muse, varscan2
- CEP128 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV55386899; called by muse, mutect2, varscan2
- CETN2 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64744949; called by muse, mutect2
- CFAP221 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV54661155; called by muse, mutect2, varscan2
- CFAP300 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV71570937; called by muse, mutect2
- CFAP45 | c.1046C>G p.A349G | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as COSV63650420; called by muse, mutect2
- CHRM2 | c.1329C>A p.C443* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as COSV57776599; called by muse, mutect2
- CHRNA2 | c.1148C>G p.P383R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53559230; called by muse, mutect2, varscan2
- CIZ1 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV52973868; called by muse, mutect2, varscan2
- CLHC1 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101284918; called by muse, mutect2
- CLTC | c.3489G>T p.K1163N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.587); catalogued as COSV52251810; called by muse, mutect2, varscan2
- CMYA5 | c.11758A>T p.I3920F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1259545208, COSV101405649, COSV69746072; called by muse, mutect2, varscan2
- CNIH2 | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV61012927; called by muse, mutect2, varscan2
- CNKSR2 | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54263725, COSV54267532; called by muse, mutect2
- CNTN1 | c.1436G>C p.G479A | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV61644132; called by muse, mutect2
- CNTNAP2 | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62207717; called by muse, mutect2
- CNTNAP4 | c.3694C>A p.L1232I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV56695743; called by muse, mutect2
- COL7A1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV60401252; called by muse, mutect2, varscan2
- COLEC11 | c.655C>A p.H219N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.068); catalogued as COSV52596433; called by muse, mutect2, varscan2
- CRNN | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV99664215; called by muse, mutect2
- CSMD3 | c.3902A>T p.D1301V (on ENST00000297405 / NM_001363185.1; = p.D1197V on NM_052900.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52281480; called by muse, mutect2, varscan2
- CTDNEP1 | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as COSV56642739; called by muse, mutect2, varscan2
- CTDSP1 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV56090104; called by muse, mutect2, varscan2
- CTNNBL1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368304027, COSV63746696; called by muse, mutect2, varscan2
- CTSK | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.207); catalogued as COSV99648840; called by muse, mutect2
- CUL3 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52368738; called by muse, mutect2, varscan2
- CYB5D1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV54678326; called by muse, mutect2, varscan2
- CYP4F22 | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV54110889, COSV54111007; called by muse, mutect2, varscan2
- DAGLB | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV51706270; called by muse, mutect2
- DAND5 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1460633175, COSV57684528; called by muse, varscan2
- DDX60 | c.4415C>G p.S1472* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV101190172, COSV101190524; called by muse, mutect2, varscan2
- DEF8 | c.334G>C p.E112Q (on ENST00000268676 / NM_207514.3; = p.E51Q on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV51920753; called by muse, mutect2, varscan2
- DEF8 | c.565G>A p.E189K (on ENST00000268676 / NM_207514.3; = p.E128K on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV51920771; called by muse, mutect2
- DENND2B | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as COSV58206826; called by muse, mutect2, varscan2
- DEPDC1 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV63958962; called by muse, mutect2
- DGKB | c.2356C>A p.P786T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.037); catalogued as rs529593415, COSV51810346; called by muse, mutect2
- DIDO1 | c.6344G>A p.R2115K | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV99826348; called by muse, mutect2
- DIDO1 | c.4306G>T p.E1436* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as COSV99826350; called by muse, mutect2
- DNA2 | c.2720A>G p.E907G | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV64429743; called by muse, mutect2, varscan2
- DNAAF3 | c.1345G>T p.E449* (on ENST00000524407 / NM_001256715.2; = p.E496* on NM_178837.4) | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100787960; called by muse, mutect2, varscan2
- DNAJC15 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as COSV64872923, COSV99061597; called by muse, mutect2, varscan2
- DNAJC6 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs947409137, COSV54779273; called by muse, mutect2
- DNM2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV58969316; called by muse, mutect2, varscan2
- DOCK10 | c.5106G>C p.W1702C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51424327; called by muse, mutect2, varscan2
- DOCK7 | c.2405G>T p.R802I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV99225026; called by muse, mutect2
- DSG4 | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV57396379; called by muse, mutect2
- DST | c.10589C>T p.S3530L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs1230102996, COSV55033660; called by muse, mutect2, varscan2
- DUSP18 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58181409; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55745105; called by muse, mutect2, varscan2
- EHBP1 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV50431315; called by muse, mutect2
- EIF4G1 | c.1441G>C p.E481Q (on ENST00000346169 / NM_198241.3; = p.E285Q on NM_004953.5) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.328); catalogued as COSV59993094; called by muse, mutect2, varscan2
- EMC8 | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53668217; called by muse, mutect2, varscan2
- EML5 | c.3958G>T p.G1320* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100714978, COSV100715903; called by muse, mutect2, varscan2
- EP300 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV99609114; called by muse, mutect2, varscan2
- EPC1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.453); catalogued as rs150143347; called by muse, mutect2, varscan2
- EPC1 | c.1480G>T p.V494F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV53928875; called by muse, mutect2
- EPM2AIP1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV51622766; called by muse, mutect2
- EPM2AIP1 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.522); catalogued as COSV51622796; called by muse, mutect2
- F8 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV64269993, COSV64277409; called by muse, mutect2, varscan2
- FADS3 | c.214-1G>T p.X72_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as rs1267541292, COSV53879990; called by muse, mutect2, varscan2
- FAM209B | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV64915578; called by muse, mutect2, varscan2
- FAT2 | c.10693A>T p.T3565S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV55820695, COSV55827032; called by muse, mutect2, varscan2
- FCGR2C | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.169); catalogued as COSV100912940; called by muse, mutect2, varscan2
- FCMR | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV65569133; called by muse, mutect2
- FFAR3 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.56); catalogued as COSV59909556; called by muse, mutect2, varscan2
- FIG4 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57790229; called by muse, mutect2, varscan2
- FMN2 | c.2579C>A p.P860H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV60447115; called by muse, mutect2, varscan2
- FNDC3B | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs749631576, COSV61047707; called by muse, mutect2, varscan2
- FOCAD | c.3079-1G>A p.X1027_splice | Splice Site (SNP) | VAF 26/85 reads (31%) | catalogued as COSV58105835; called by muse, mutect2, varscan2
- FREM2 | c.8375C>A p.P2792Q | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54847848; called by muse, mutect2
- FSCB | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV61219259; called by muse, mutect2
- GBP4 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63255591; called by muse, mutect2
- GBP4 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.049); catalogued as COSV100864426, COSV63252865; called by muse, mutect2
- GDPD1 | c.548A>T p.Y183F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs748762189, COSV52383798; called by muse, mutect2, varscan2
- GET4 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs573133720, COSV56256303; called by muse, mutect2, varscan2
- GHSR | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV53841005; called by muse, mutect2, varscan2
- GNAQ | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV54122349; called by muse, mutect2
- GNAT2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV63555274; called by muse, mutect2, varscan2
- GNL3 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV66917755; called by muse, mutect2, varscan2
- GP9 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770361254, COSV56624685; called by muse, mutect2, varscan2
- GPN3 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV57400262; called by muse, mutect2, varscan2
- GPRASP2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59992208; called by muse, mutect2, varscan2
- GRID2 | c.2421G>C p.K807N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV56248810; called by muse, mutect2, varscan2
- GRM4 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65217858; called by muse, mutect2
- GTF2H3 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57459723; called by muse, mutect2
- HAO1 | c.671G>T p.W224L | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV66493417; called by muse, mutect2, varscan2
- HECTD1 | c.6598C>T p.P2200S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.3); catalogued as COSV101237424; called by muse, mutect2
- HELZ | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV62380280; called by muse, mutect2, varscan2
- HEPH | c.3164G>T p.G1055V (on ENST00000343002; = p.G788V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1320619755, COSV100295161; called by muse, mutect2
- HLF | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV56831373; called by muse, mutect2, varscan2
- HOXA1 | c.89C>G p.S30W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.715); catalogued as COSV56067447; called by muse, mutect2, varscan2
- HOXC10 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV57726933; called by muse, mutect2, varscan2
- HSD17B6 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV59108565; called by muse, mutect2, varscan2
- IFT81 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs1435114143, COSV54361589; called by muse, varscan2
- IGSF10 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV56790264; called by muse, mutect2, varscan2
- ITGA6 | c.2965C>G p.L989V (on ENST00000442250; = p.L950V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs953949763, COSV51247912; called by muse, mutect2, varscan2
- ITGB4 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1361265679, COSV52331132; called by muse, mutect2, varscan2
- JADE2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV50926760; called by muse, mutect2, varscan2
- KAT6A | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV55910834; called by muse, mutect2, varscan2
- KCNK6 | c.333C>G p.Y111* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99649410; called by muse, mutect2
- KCNMB1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.577); catalogued as COSV51134743; called by muse, mutect2, varscan2
- KIDINS220 | c.3514C>G p.Q1172E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs768490849, COSV56757761; called by muse, mutect2, varscan2
- KLHL3 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV59056949; called by muse, mutect2, varscan2
- KLRF1 | c.540G>C p.L180F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV54381629; called by muse, mutect2
- KRT14 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51422707; called by muse, mutect2, varscan2
- KRT17 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60861700; called by muse, mutect2
- LAMA1 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101056912; called by muse, mutect2
- LCOR | c.4398G>C p.K1466N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53717833; called by muse, mutect2, varscan2
- LEPROT | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100756658; called by muse, mutect2
- LILRB1 | c.1031C>A p.S344* (on ENST00000427581; = p.S308* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as rs375583070, COSV100207506; called by muse, mutect2, varscan2
- LILRB5 | c.1707G>T p.E569D (on ENST00000449561 / NM_001081442.3; = p.E568D on NM_006840.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV60260193; called by muse, mutect2, varscan2
- LPA | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 9/630 reads (1%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.988); catalogued as rs1451786395, COSV100307374; called by muse, mutect2
- LRCH1 | c.1825G>C p.G609R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60851833; called by muse, mutect2, varscan2
- LRFN5 | c.156A>T p.R52S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV99984531; called by muse, mutect2
- LRP1B | c.6331G>T p.G2111C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs748808497, COSV67208021, COSV67260504; called by muse, mutect2, varscan2
- LRRC31 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.28); catalogued as COSV99246877; called by muse, mutect2
- LRRC3B | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67520786; called by muse, mutect2
- LRRC41 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs755081127, COSV58441759; called by muse, mutect2, varscan2
- LRRC7 | c.1269C>A p.F423L (on ENST00000651989 / NM_001370785.2; = p.F390L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV50410174; called by muse, mutect2
- LRRK2 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV100109194, COSV54154202; called by muse, mutect2, varscan2
- MAGEB6 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.391); catalogued as COSV66872845; called by muse, mutect2, varscan2
- MAN2A1 | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs752558998, COSV54856893; called by muse, mutect2, varscan2
- MAP1B | c.6502G>C p.E2168Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57104352; called by muse, mutect2, varscan2
- MAP3K20 | c.627G>T p.L209F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.377); catalogued as COSV59105547; called by muse, mutect2, varscan2
- MAP4 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as rs1231026190, COSV100805999; called by muse, mutect2
- MATN4 | c.1396G>T p.G466W (on ENST00000372754; = p.G425W on NM_003833.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | PolyPhen probably damaging (1); catalogued as COSV61352459; called by muse, mutect2, varscan2
- MCRS1 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV99235455; called by muse, mutect2
- MECOM | c.127C>T p.P43S (on ENST00000468789 / NM_001105078.4; = p.P231S on NM_004991.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.027); catalogued as COSV52971742; called by muse, mutect2
- MKI67 | c.9231C>G p.H3077Q | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.26); catalogued as COSV64076161; called by muse, mutect2
- MKI67 | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as rs1328916610, CM142485, COSV100896745; called by muse, mutect2, varscan2
- MRPL18 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV99277636; called by muse, mutect2
- MSH2 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs41295286, COSV51883407; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- MSL3 | c.994C>G p.P332A (on ENST00000312196 / NM_078629.4; = p.P166A on NM_006800.4) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56495293; called by muse, mutect2
- MTFMT | c.903A>T p.L301F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54979275; called by muse, mutect2, varscan2
- MTHFD1L | c.2282C>A p.P761H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66226911; called by muse, mutect2
- MTMR1 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64897480, COSV64899333; called by muse, mutect2, varscan2
- MUC5B | c.14817C>G p.F4939L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV101500515; called by muse, mutect2
- MUSK | c.1721A>G p.N574S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1358028791, COSV99504588; called by muse, mutect2
- MYH15 | c.3750G>C p.M1250I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV56317197; called by muse, mutect2, varscan2
- MYO18A | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV62871876; called by muse, mutect2
- MYOT | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV53516012; called by muse, mutect2, varscan2
- NAT8 | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs566417657, COSV55542942, COSV99722083; called by muse, mutect2, varscan2
- NAV2 | c.3109G>C p.D1037H (on ENST00000396087 / NM_001244963.2; = p.D1014H on NM_145117.5) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60663562, COSV60663638; called by muse, mutect2
- NDST4 | c.736T>C p.S246P | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52132589; called by muse, mutect2, varscan2
- NEB | c.3141C>G p.I1047M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.805); catalogued as COSV51447807; called by mutect2, varscan2
- NECAB1 | c.969C>A p.F323L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70243260, COSV70245650; called by muse, mutect2
- NGEF | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV50914726, COSV50943982; called by muse, mutect2, varscan2
- NIBAN3 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.356); catalogued as rs763507295, COSV56312904; called by muse, mutect2, varscan2
- NIPBL | c.3519G>T p.K1173N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1447813242, COSV56961808, COSV56968148; called by muse, mutect2, varscan2
- NMU | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51701463; called by muse, mutect2, varscan2
- NOP2 | c.2152G>A p.A718T (on ENST00000322166 / NM_001258308.2; = p.A714T on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV59112908; called by muse, mutect2, varscan2
- NTNG1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53965690; called by muse, mutect2, varscan2
- NUP155 | c.790C>A p.L264I (on ENST00000231498 / NM_153485.3; = p.L205I on NM_004298.4) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); catalogued as COSV51533481; called by muse, mutect2, varscan2
- NUP160 | c.3838A>G p.K1280E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs774690512, COSV65855527; called by muse, mutect2, varscan2
- NYAP1 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.889); catalogued as rs773343242, COSV55721175; called by muse, mutect2, varscan2
- OGDH | c.2079G>C p.Q693H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56055311; called by muse, mutect2, varscan2
- OPHN1 | c.2263C>G p.Q755E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as COSV62785692; called by muse, mutect2, varscan2
- OPTN | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs759022584, COSV53812522; called by muse, mutect2, varscan2
- OR10A2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56300169; called by muse, mutect2, varscan2
- OR10AG1 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV56633472; called by muse, mutect2, varscan2
- OR10R2 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs780673528, COSV63769171, COSV63769343; called by muse, mutect2
- OR4C16 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV58942099, COSV58943641; called by mutect2, varscan2
- OR4Q3 | c.658T>A p.F220I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59179840; called by muse, mutect2, varscan2
- OR51V1 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV58316061; called by muse, mutect2, varscan2
- OR56B4 | c.499A>T p.I167L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV57205308; called by muse, mutect2, varscan2
- OR5AK2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372725475, COSV58805334; called by muse, mutect2, varscan2
- OR5B3 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1015561186, COSV100512029, COSV58678372; called by muse, mutect2
- OR5W2 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV60617889; called by muse, mutect2, varscan2
- OR5W2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV60617296; called by muse, mutect2, varscan2
- OR6C68 | c.648C>A p.Y216* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV101110035; called by muse, mutect2, varscan2
- OR8G1 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1224930723, COSV58382592; called by muse, mutect2
- ORC3 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | catalogued as rs879074350, COSV100006056; called by muse, mutect2, varscan2
- OSBP | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 27/150 reads (18%) | catalogued as COSV99803149; called by muse, mutect2, varscan2
- PCDHA5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65354658; called by muse, mutect2, varscan2
- PCDHGA8 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99541752; called by muse, mutect2, varscan2
- PCDHGB1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54008376; called by muse, mutect2
- PDGFRA | c.3250G>A p.V1084M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV57271098; called by muse, mutect2, varscan2
- PDIA6 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.109); catalogued as rs371267030, COSV55352720; called by muse, mutect2, varscan2
- PEX1 | c.3253G>C p.V1085L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV99952248; called by muse, mutect2
- PFKFB1 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | PolyPhen benign (0.191); catalogued as rs1352931712, COSV66629124; called by muse, mutect2, varscan2
- PHF20 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59188174; called by muse, mutect2, varscan2
- PHTF2 | c.1160C>T p.S387L (on ENST00000248550 / NM_001366089.1; = p.S349L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV99301984; called by muse, mutect2
- PICK1 | c.350-2A>G p.X117_splice | Splice Site (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100811109; called by muse, mutect2
- PLA2G12B | c.309G>T p.L103F | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV65979016; called by muse, mutect2, varscan2
- PLCL1 | c.582C>A p.H194Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV70863753, COSV70871450; called by muse, mutect2, varscan2
- PLSCR1 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV61013134; called by muse, mutect2, varscan2
- PLXNA3 | c.3924C>G p.F1308L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100860078, COSV63754092; called by muse, mutect2
- PML | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV51451990; called by muse, mutect2
- POF1B | c.1400T>A p.L467* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV53140663; called by muse, mutect2
- POLR3C | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV57908031, COSV57908248; called by muse, mutect2
- PPHLN1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV56735239; called by muse, mutect2, varscan2
- PPP1R3A | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV52890475; called by muse, mutect2, varscan2
- PRELID3B | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs377238736, COSV63505207, COSV99054454; called by muse, mutect2, varscan2
- PRPF6 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53876371; called by muse, mutect2, varscan2
- PSMA5 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99600579; called by muse, mutect2
- PTPRT | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs750249800, COSV61981677, COSV62009319; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1239C>T p.F413= | Splice Region (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99921366; called by muse, mutect2
- RAB6A | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60179723; called by muse, mutect2, varscan2
- RALGAPB | c.1584G>C p.K528N | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99485440; called by muse, mutect2
- RB1CC1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50267357; called by muse, mutect2
- RBM12 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs770210216, COSV58294118; called by muse, mutect2, varscan2
- RRM1 | c.1029G>C p.E343D | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV56162974, COSV56165646; called by muse, mutect2
- RSF1 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV57844311; called by muse, mutect2
- RYR1 | c.7891C>T p.P2631S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV62094998; called by muse, mutect2, varscan2
- SCAI | c.373G>C p.E125Q (on ENST00000336505 / NM_001144877.3; = p.E148Q on NM_173690.5) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60616623; called by muse, mutect2
- SEC14L1 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV66724540; called by muse, mutect2, varscan2
- SEC63 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100938433; called by muse, mutect2, varscan2
- SEPHS2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.772); catalogued as rs1248028534, COSV72100813; called by muse, mutect2, varscan2
- SF3A1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53168005; called by muse, mutect2
- SFXN5 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1470139171, COSV99242202; called by muse, mutect2
- SIPA1L2 | c.1485G>A p.E495= | Splice Region (SNP) | VAF 16/123 reads (13%) | catalogued as rs367614664, COSV53397314; called by muse, mutect2, varscan2
- SLC23A1 | c.1724C>G p.S575* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV99497300; called by muse, mutect2, varscan2
- SLC25A11 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52591873; called by muse, mutect2, varscan2
- SLC25A30 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV60434377; called by muse, mutect2
- SLC26A3 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60639880; called by muse, mutect2, varscan2
- SLC2A10 | c.921G>T p.M307I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV63715734; called by muse, mutect2, varscan2
- SLC6A15 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57020946, COSV57027800; called by muse, mutect2, varscan2
- SLC8B1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52526043, COSV52529999; called by muse, mutect2, varscan2
- SLC9A7 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1160191320, COSV60378558; called by muse, mutect2, varscan2
- SLITRK4 | c.487A>T p.N163Y | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62025648; called by muse, mutect2, varscan2
- SNAPC4 | c.405C>G p.S135R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV100047434; called by muse, mutect2
- SORL1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99494470; called by muse, mutect2, varscan2
- SOS2 | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.125); catalogued as COSV53572499; called by muse, mutect2
- SPATA31D1 | c.2857C>G p.Q953E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61199899; called by muse, mutect2, varscan2
- SPTA1 | c.4787C>A p.T1596K | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63757667; called by muse, mutect2
- ST3GAL3 | c.697G>C p.E233Q (on ENST00000361392 / NM_174964.4; = p.E218Q on NM_006279.5) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV99495538, COSV99495639, COSV99496130; called by muse, mutect2
- STK11IP | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs553152265, COSV99823078; called by muse, mutect2
- STXBP6 | c.89A>T p.K30M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100121962; called by muse, mutect2
- SUSD1 | c.1518C>A p.C506* | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100813386; called by muse, mutect2
- SYNE2 | c.14083G>A p.E4695K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as COSV59964646; called by muse, mutect2, varscan2
- SYNM | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV60373690; called by muse, mutect2, varscan2
- SYT2 | c.1018T>A p.S340T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV66142804; called by muse, mutect2
- SZT2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV101285374; called by muse, mutect2
- TACO1 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV51976318; called by muse, mutect2, varscan2
- TCHHL1 | c.1544G>T p.R515M | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs151016610, COSV64287080; called by muse, mutect2, varscan2
- TDGF1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs759659226, COSV56128146; called by mutect2, varscan2
- TENM1 | c.3441A>T p.Q1147H | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV64440050; called by muse, mutect2, varscan2
- TEX13A | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV61174497; called by muse, mutect2, varscan2
- THSD7B | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55664359; called by muse, mutect2, varscan2
- TLR4 | c.1105G>T p.E369* (on ENST00000355622 / NM_138554.5; = p.E329* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100842808; called by muse, mutect2, varscan2
- TM6SF1 | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV51945889; called by muse, mutect2, varscan2
- TNS3 | c.3418G>T p.D1140Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60790516, COSV60796758; called by muse, mutect2, varscan2
- TOMM70 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345293694, COSV52524834; called by muse, mutect2
- TRIM38 | c.176G>C p.C59S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62642731; called by muse, mutect2, varscan2
- TRIM39 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.386); catalogued as rs1474816612, COSV64956327; called by muse, mutect2, varscan2
- TRIM9 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031727, COSV100031762; called by muse, mutect2
- TRRAP | c.4255G>A p.E1419K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV62851965; called by muse, mutect2
- TSNAXIP1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326568867, COSV54651588; called by muse, mutect2, varscan2
- TTN | c.36490A>T p.N12164Y (on ENST00000591111; = p.N4740Y on NM_003319.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | PolyPhen probably damaging (0.914); catalogued as COSV60267076; called by muse, mutect2, varscan2
- TTN | c.34974A>T p.E11658D (on ENST00000591111; = p.E10731D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | PolyPhen probably damaging (0.98); catalogued as COSV60267103; called by muse, mutect2, varscan2
- TXNDC2 | c.215C>A p.T72K (on ENST00000306084 / NM_001098529.2; = p.T5K on NM_032243.6) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV60155084; called by muse, mutect2, varscan2
- TYK2 | c.1177del p.V393Sfs*13 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as COSV53390757; called by mutect2, pindel, varscan2
- UBA2 | c.872-2A>C p.X291_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV55829829; called by muse, varscan2
- UBR2 | c.2309G>C p.G770A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV65751946; called by muse, mutect2, varscan2
- UBR5 | c.4663C>T p.R1555W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55296528; called by muse, mutect2, varscan2
- UGGT1 | c.3536A>G p.Y1179C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV52140137; called by muse, mutect2, varscan2
- UNC13C | c.3394G>A p.G1132R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV52910963; called by muse, mutect2, varscan2
- USP11 | c.1570G>C p.D524H (on ENST00000218348; = p.D481H on NM_001371072.1) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99511023; called by muse, mutect2
- USP9X | c.4746G>C p.R1582S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61073814; called by muse, mutect2
- UVSSA | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV101104523; called by muse, mutect2
- VCAN | c.5107A>G p.T1703A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV54113828; called by muse, mutect2
- VILL | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV52183308, COSV52185436; called by muse, mutect2
- VWA3B | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV68245742; called by muse, mutect2, varscan2
- WASHC4 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765881333, COSV59891504; called by muse, mutect2, varscan2
- WDR20 | c.774G>C p.M258I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV54474323; called by muse, mutect2, varscan2
- WIPF1 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99769012; called by muse, mutect2, varscan2
- XPO6 | c.390T>A p.F130L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.121); catalogued as COSV100485170; called by muse, mutect2
- XYLT1 | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54493559; called by muse, mutect2, varscan2
- ZBTB12 | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100977025; called by muse, mutect2
- ZBTB22 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV56471924; called by mutect2, varscan2
- ZDHHC9 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV64097223; called by muse, mutect2, varscan2
- ZNF208 | c.3041C>G p.S1014* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as rs759100623, COSV101237042, COSV101237101; called by muse, mutect2, varscan2
- ZNF222 | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV51827935; called by muse, mutect2, varscan2
- ZNF253 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV63038235; called by muse, mutect2, varscan2
- ZNF304 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56585943; called by muse, mutect2, varscan2
- ZNF460 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as COSV64416251; called by muse, mutect2, varscan2
- ZNF474 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV56947189; called by muse, mutect2, varscan2
- ZNF560 | c.1530C>A p.H510Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56868808, COSV56870653; called by muse, mutect2, varscan2
- ZNF613 | c.205G>A p.E69K (on ENST00000293471 / NM_001031721.4; = p.E33K on NM_024840.4) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs1157413579, COSV53273392; called by muse, mutect2, varscan2
- ZNF652 | c.802C>G p.H268D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62948416; called by muse, mutect2, varscan2
- ZNF669 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV58538976, COSV99057683; called by muse, mutect2
- ZNF699 | c.1262G>T p.C421F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58026630; called by muse, mutect2, varscan2
- ZNF746 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV61408552; called by muse, mutect2, varscan2
- ZNF773 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV56589978; called by muse, mutect2, varscan2
- CDKN2A | c.299_302dup p.A102Rfs*19 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- KIR3DL3 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2
- MYLK | c.3131_3166del p.A1044_P1055del | In Frame Del (DEL) | VAF 28/253 reads (11%) | called by muse*, mutect2
- PLEKHO1 | c.390del p.I131Sfs*42 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- POLR2A | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.195); called by muse, mutect2
- SHANK3 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- XAGE2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ABCA8 | c.2388T>G p.G796= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV52209289; called by muse, mutect2, varscan2
- ABCC2 | c.3196C>A p.R1066= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as CM973223, COSV64988050; called by muse, mutect2, varscan2
- ABCC9 | c.1335G>T p.V445= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53982429; called by muse, mutect2, varscan2
- AC004922.1 | c.657G>T p.L219= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53558659; called by muse, mutect2, varscan2
- ADAM18 | c.366T>C p.N122= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV55852945; called by muse, mutect2, varscan2
- ADGRE1 | c.2124C>T p.I708= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV51679556; called by muse, mutect2, varscan2
- ADGRG1 | c.1827G>T p.V609= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101113477; called by mutect2, varscan2
- AK7 | c.723A>T p.P241= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV50879449; called by muse, mutect2
- ALK | c.3861C>A p.G1287= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV66584574; called by muse, mutect2, varscan2
- ANKS1B | c.1455A>T p.V485= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV61368712; called by muse, mutect2, varscan2
- ARHGEF12 | c.1572C>A p.A524= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1220244353, COSV63106734; called by muse, mutect2, varscan2
- ARHGEF40 | c.1200G>T p.L400= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV53883307; called by muse, varscan2
- ATP8B1 | c.669C>G p.L223= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV52179017; called by muse, mutect2
- C5AR2 | c.523C>T p.L175= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV57257039; called by muse, mutect2, varscan2
- CACNA1B | c.6867C>A p.G2289= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV53142539; called by muse, mutect2
- CCDC153 | c.510G>C p.L170= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59539089, COSV59541279; called by muse, mutect2, varscan2
- CCDC186 | c.1495A>C p.R499= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV65161885; called by muse, mutect2, varscan2
- CCDC3 | c.492G>T p.S164= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs770704967, COSV66561316; called by muse, mutect2, varscan2
- CDH18 | c.42G>A p.V14= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1341909009, COSV56951307; called by muse, mutect2
- CLCN4 | c.399G>A p.Q133= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV66467964; called by muse, mutect2, varscan2
- CMA1 | c.435G>T p.R145= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV51626110; called by muse, mutect2
- COL17A1 | c.4485C>G p.V1495= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59828125; called by muse, mutect2, varscan2
- DDX23 | c.1192C>T p.L398= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV57285546; called by muse, mutect2, varscan2
- DGKB | c.405G>A p.L135= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV51810359; called by muse, mutect2
- DHRS7C | c.381T>C p.N127= (on ENST00000330255 / NM_001220493.2; = p.N126= on NM_001105571.3) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57652161; called by muse, mutect2, varscan2
- DHX58 | c.1665C>G p.L555= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV52427703; called by muse, mutect2, varscan2
- DHX58 | c.1419G>C p.R473= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV52427717; called by muse, mutect2, varscan2
- DMTF1 | c.1398G>A p.Q466= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV58687614; called by muse, mutect2
- DVL2 | c.1539G>A p.E513= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as rs1411800827, COSV50038642; called by muse, mutect2
- DZANK1 | c.1518A>G p.A506= (on ENST00000262547 / NM_001099407.1; = p.A313= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV52755800; called by muse, mutect2, varscan2
- EPHA1 | c.1380G>A p.P460= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs746374059, COSV51975022; called by muse, mutect2, varscan2
- EPS8L3 | c.561G>A p.G187= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1260768819, COSV62610337; called by muse, mutect2, varscan2
- F8 | c.4965C>T p.C1655= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV64277406; called by muse, mutect2, varscan2
- FAT2 | c.6729C>G p.V2243= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV55827042; called by muse, mutect2, varscan2
- FLRT3 | c.1182C>A p.P394= | Silent (SNP) | VAF 14/185 reads (8%) | catalogued as COSV54035072; called by muse, mutect2
- FREM2 | c.4554C>G p.V1518= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV54847834; called by muse, mutect2
- GABPB2 | c.552C>T p.F184= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV64461365; called by muse, mutect2
- GNG3 | c.225C>G p.L75= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV53655490; called by muse, mutect2, varscan2
- GPBP1L1 | c.372C>T p.F124= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV51972170; called by muse, mutect2, varscan2
- GPR15 | c.1080C>G p.L360= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99423846; called by muse, mutect2
- H2BC21 | c.222C>T p.I74= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV58611965; called by muse, mutect2
- HABP2 | c.1362T>C p.V454= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV63493186; called by muse, mutect2, varscan2
- HEATR6 | c.3024G>T p.V1008= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as rs1157133382, COSV99482450; called by muse, mutect2
- HECTD3 | c.816C>T p.S272= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs570854697, COSV55800548; called by muse, mutect2, varscan2
- IGSF10 | c.678T>C p.H226= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV56790273; called by muse, mutect2, varscan2
- IQCC | c.1134G>A p.E378= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1237627530, COSV99356692; called by muse, mutect2
- ITGB4 | c.1191C>G p.S397= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV52331145; called by muse, mutect2, varscan2
- KCNH7 | c.2637C>A p.S879= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV59809200; called by muse, mutect2, varscan2
- KCNV1 | c.1482G>T p.G494= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV52084668, COSV52088454; called by muse, mutect2, varscan2
- LBHD1 | c.418A>C p.R140= (on ENST00000431002 / NM_001367940.1; = p.R114= on NM_024099.3) | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as COSV63473421, COSV63473561; called by muse, mutect2, varscan2
- LIMA1 | c.411C>T p.L137= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs769930517, COSV57967831; called by muse, mutect2, varscan2
- MACC1 | c.2317C>A p.R773= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV60541074, COSV60545538; called by muse, mutect2, varscan2
- MCTP2 | c.2592C>G p.L864= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV63296451; called by muse, mutect2, varscan2
- MRPL32 | c.306A>G p.K102= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV56238505; called by muse, mutect2, varscan2
- MYO1G | c.171G>T p.L57= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1289610262, COSV51856503; called by muse, mutect2, varscan2
- NCK1 | c.552T>C p.N184= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs1327097555, COSV56639194; called by muse, mutect2, varscan2
- NCKAP5L | c.582G>C p.L194= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100259004, COSV60132561; called by muse, mutect2, varscan2
- NF1 | c.3438C>A p.V1146= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV62215582; called by muse, mutect2, varscan2
- NHLRC3 | c.144G>T p.L48= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100612712, COSV61489077; called by muse, mutect2
- NUDT17 | c.550C>T p.L184= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100492987; called by muse, mutect2
- NUP98 | c.3723G>A p.L1241= (on ENST00000359171 / NM_001365126.1; = p.L1224= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV61437017; called by muse, mutect2, varscan2
- OR1L4 | c.51C>A p.G17= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV52341208; called by muse, mutect2
- OR2F2 | c.402C>A p.A134= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV68833204; called by muse, mutect2, varscan2
- OR2T2 | c.840C>A p.T280= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100737723; called by muse, mutect2
- OR8D1 | c.783G>A p.K261= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV63442874; called by muse, mutect2, varscan2
- PARP15 | c.1338C>T p.V446= (on ENST00000464300 / NM_001113523.3; = p.V212= on NM_152615.2) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV59974372; called by muse, varscan2
- PDE1B | c.1227C>G p.L409= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV54491823, COSV54495294; called by muse, mutect2
- PHF20 | c.1074G>C p.T358= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV59188180; called by muse, mutect2, varscan2
- POR | c.1893C>G p.V631= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58694928; called by muse, mutect2, varscan2
- PPIP5K2 | c.507G>A p.G169= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV58608620; called by muse, mutect2, varscan2
- PRDM9 | c.1062G>T p.L354= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV57007922; called by muse, mutect2, varscan2
- PRKACA | c.459G>T p.L153= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100431937, COSV58069686; called by muse, varscan2
- PSG3 | c.1173C>T p.L391= | Silent (SNP) | VAF 24/218 reads (11%) | catalogued as COSV59506322; called by muse, mutect2, varscan2
- PTPRT | c.453C>G p.L151= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV61962190, COSV61991072, COSV62009332; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2280G>T p.V760= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1266631548, COSV54762976; called by mutect2, varscan2
- RBP7 | c.261T>C p.V87= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV53813662; called by muse, mutect2
- REG1B | c.210C>A p.G70= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1170377751, COSV59307307; called by muse, mutect2
- ROPN1L | c.558G>A p.E186= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV56874747; called by muse, mutect2, varscan2
- RP1 | c.2253C>A p.S751= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV55123997; called by muse, mutect2, varscan2
- RTN3 | c.1821G>A p.E607= (on ENST00000377819 / NM_001265589.2; = p.E588= on NM_201428.3) | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV58031127; called by muse, mutect2, varscan2
- RTP1 | c.720C>T p.P240= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1187862565, COSV56619253; called by muse, mutect2
- SALL2 | c.558A>G p.L186= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV58105257; called by muse, mutect2, varscan2
- SIPA1L3 | c.4863C>G p.L1621= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as COSV55921889; called by muse, mutect2, varscan2
- SLC6A2 | c.690C>T p.I230= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs781578719, COSV54915542; ClinVar: likely benign; called by muse, mutect2
- SLC9A3 | c.1719G>T p.T573= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV53804376; called by muse, mutect2, varscan2
- SOWAHC | c.1368A>G p.P456= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV61781639; called by mutect2, varscan2
- SPAG4 | c.1137G>A p.E379= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1488412557, COSV65329958, COSV65330792, COSV65330934; called by muse, mutect2, varscan2
- SPATA4 | c.147C>A p.S49= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV54591354; called by muse, mutect2, varscan2
- TASOR2 | c.2934C>A p.T978= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV60169056; called by muse, mutect2, varscan2
- TLR4 | c.210C>G p.G70= (on ENST00000355622 / NM_138554.5; = p.G30= on NM_003266.4) | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV62924003; called by muse, mutect2
- TMEM116 | c.294C>T p.L98= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs372986676; called by mutect2, varscan2
- TMEM79 | c.612G>T p.V204= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1019713785, COSV55296928; called by muse, mutect2, varscan2
- TP53I3 | c.318C>A p.L106= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99475457; called by muse, mutect2
- UMOD | c.897G>A p.E299= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV56778668; called by muse, mutect2, varscan2
- WDR20 | c.1425G>A p.E475= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100085213, COSV54472052; called by muse, mutect2
- ZFX | c.276C>T p.I92= | Silent (SNP) | VAF 7/196 reads (4%) | catalogued as COSV58449439; called by muse, mutect2
- ZKSCAN5 | c.801C>T p.L267= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as rs1445837494, COSV58744168; called by muse, mutect2
- ZNF804B | c.3801C>G p.P1267= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100302883, COSV60847285; called by muse, mutect2, varscan2
- AL590867.2 | n.96C>T | RNA (SNP) | VAF 10/90 reads (11%) | catalogued as rs972701104; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620374 C>A | 3'Flank (SNP) | VAF 42/499 reads (8%) | catalogued as COSV54089669; called by muse, mutect2
- CFAP46 | c.966+24G>C | Intron (SNP) | VAF 12/85 reads (14%) | catalogued as COSV63953786; called by muse, mutect2, varscan2
- CFAP74 | c.4653+273C>T | Intron (SNP) | VAF 3/32 reads (9%) | catalogued as COSV60587974; called by muse, mutect2
- EBAG9 | c.522-1009C>A | Intron (SNP) | VAF 119/276 reads (43%) | catalogued as COSV61753548; called by muse, mutect2, varscan2
- GLIS3 | c.-15G>T | 5'UTR (SNP) | VAF 30/68 reads (44%) | catalogued as rs1161898289, COSV100175069, COSV60933835; called by muse, mutect2, varscan2
- LINC00922 | n.886G>A | RNA (SNP) | VAF 6/59 reads (10%) | catalogued as rs530892188; called by mutect2, varscan2
- MAPK1IP1L | c.-15G>C | 5'UTR (SNP) | VAF 6/84 reads (7%) | catalogued as rs1441452155, COSV100216240; called by muse, mutect2
- TEX2 | chr17:64146370 C>T | 3'Flank (SNP) | VAF 7/98 reads (7%) | catalogued as rs1321955599; called by muse, mutect2
